Somatic mutation profile of tumor specimen TCGA-25-2398-01A (aliquot TCGA-25-2398-01A-01D-0704-01) from TCGA case TCGA-25-2398, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-25-2398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80440e21-b662-4ec8-be6c-38473b0d2e1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2398-10A (Blood Derived Normal), aliquot TCGA-25-2398-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e3a17c6-8398-4141-9b5d-4a685827329f

The open-access MAF lists 66 somatic variants for this specimen: 47 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, Translation Start Site 1, Nonstop Mutation 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS13 | c.105+2T>C p.X35_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100747105; called by mutect2, varscan2
- ARHGAP35 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101351157; called by muse, varscan2
- ARHGAP35 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101351160; called by muse, varscan2
- ARHGAP35 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 75/245 reads (31%) | catalogued as COSV68329637; called by muse, mutect2, varscan2
- CAPN12 | c.2051T>C p.V684A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99400301; called by muse, mutect2, varscan2
- CETN1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59121006; called by muse, mutect2, varscan2
- CLEC14A | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60561928; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1385012062, COSV62567000, COSV62570201; called by muse, varscan2
- FAM122A | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV99599020; called by muse, mutect2
- GPR141 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs766476489, COSV57731549; called by muse, mutect2, varscan2
- GPR142 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV59518799; called by muse, mutect2, varscan2
- IL21R | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61968824; called by muse, mutect2, varscan2
- JCAD | c.2138C>G p.P713R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.257); catalogued as COSV64758356; called by muse, mutect2, varscan2
- KREMEN1 | c.1256C>T p.S419F (on ENST00000407188; = p.S421F on NM_032045.5) | Missense Mutation (SNP) | VAF 91/159 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs1410461495, COSV59911803; called by muse, mutect2, varscan2
- MAGI2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.703); catalogued as rs776534735, COSV62639280; called by muse, mutect2, varscan2
- MGRN1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs747300145, COSV52149027; called by muse, mutect2, varscan2
- MRPS26 | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99848666; called by muse, mutect2, varscan2
- MUC2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.01); catalogued as COSV100364444; called by muse, mutect2
- MUC21 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 40/632 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV66220367; called by muse, mutect2
- MYO7A | c.4190T>G p.F1397C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101289156; called by muse, mutect2, varscan2
- NCAN | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99387406; called by muse, mutect2, varscan2
- OCA2 | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62340463; called by muse, varscan2
- OR6A2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373299055; called by muse, mutect2, varscan2
- PDE1B | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54490346; called by muse, mutect2
- PFKP | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66889980; called by muse, mutect2, varscan2
- PROSER1 | c.2390C>G p.P797R | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV61486683; called by muse, mutect2
- PSD | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV50042424; called by muse, mutect2, varscan2
- RBL2 | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777931235, COSV50873696; called by muse, mutect2, varscan2
- RPL39L | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs762053308, COSV56219858; called by muse, mutect2, varscan2
- RYR1 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62091501; called by muse, mutect2
- RYR3 | c.3029A>G p.D1010G | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212917; called by muse, mutect2, varscan2
- SYNE2 | c.20123A>C p.Q6708P | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59942148; called by muse, mutect2, varscan2
- TNFRSF9 | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV66348846; called by muse, mutect2, varscan2
- TRIM10 | c.1445G>C p.*482Sext*34 | Nonstop Mutation (SNP) | VAF 30/402 reads (7%) | catalogued as COSV100939719; called by muse, mutect2
- TRIM10 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100939722; called by muse, mutect2
- TRIM40 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100325380; called by muse, mutect2
- TRMT1 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV55564817; called by muse, mutect2, varscan2
- TUBB4A | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.505); catalogued as rs745756691, COSV51152512; called by muse, mutect2, varscan2
- YBX1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV58437431, COSV58437510; called by muse, mutect2, varscan2
- ZNF217 | c.2996G>C p.C999S | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV56594706, COSV56597808; called by muse, mutect2, varscan2
- ZNF441 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV63539224; called by muse, mutect2, varscan2
- ZNF486 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100631289; called by muse, mutect2, varscan2
- ZNF776 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV57814613; called by muse, mutect2, varscan2
- ARHGAP35 | c.4041del p.N1348Tfs*14 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, varscan2
- DHX38 | c.967del p.D323Ifs*6 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | called by mutect2, pindel*, varscan2
- LAMC1 | c.3619dup p.T1207Nfs*4 | Frame Shift Ins (INS) | VAF 21/159 reads (13%) | called by mutect2, pindel, varscan2
- PCSK7 | c.1101del p.C367Wfs*20 | Frame Shift Del (DEL) | VAF 31/162 reads (19%) | called by mutect2, pindel, varscan2
- A2ML1 | c.921G>A p.A307= | Silent (SNP) | VAF 41/256 reads (16%) | catalogued as rs372520121; called by muse, mutect2, varscan2
- ALPK2 | c.3867C>T p.A1289= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs781369958, COSV64490877; called by muse, mutect2, varscan2
- ARHGAP35 | c.768C>T p.I256= | Silent (SNP) | VAF 33/182 reads (18%) | catalogued as COSV101351143; called by muse, mutect2, varscan2
- ARHGAP35 | c.964C>T p.L322= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV101351147; called by muse, mutect2, varscan2
- ARMCX2 | c.435G>A p.V145= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs782329599, COSV57529426; called by muse, varscan2
- FBXO15 | c.1437G>T p.L479= | Silent (SNP) | VAF 54/313 reads (17%) | catalogued as COSV54043304; called by muse, mutect2, varscan2
- INO80 | c.4137C>T p.D1379= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV62736563; called by muse, mutect2, varscan2
- MTIF3 | c.483G>T p.L161= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as rs138161348; called by muse, mutect2, varscan2
- MUC21 | c.6G>A p.K2= | Silent (SNP) | VAF 13/399 reads (3%) | catalogued as COSV66220363; called by muse, mutect2
- NPR1 | c.2025G>A p.K675= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV64117365; called by muse, mutect2, varscan2
- PIK3IP1 | c.711G>C p.V237= | Silent (SNP) | VAF 72/101 reads (71%) | catalogued as COSV53223142; called by muse, mutect2, varscan2
- SENP7 | c.2589C>T p.L863= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs768736955, COSV58609102; called by mutect2, varscan2
- TIMELESS | c.2268T>C p.S756= | Silent (SNP) | VAF 29/226 reads (13%) | catalogued as COSV57509602; called by muse, mutect2, varscan2
- TRPV5 | c.904C>A p.R302= | Silent (SNP) | VAF 38/166 reads (23%) | catalogued as COSV54683675, COSV54686970; called by muse, mutect2, varscan2
- ZGPAT | c.924T>C p.S308= | Silent (SNP) | VAF 26/483 reads (5%) | catalogued as COSV100203181; called by muse, mutect2
- ZNF212 | c.1452G>A p.L484= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as COSV60024675; called by muse, mutect2
- ZNF611 | c.1821A>T p.S607= | Silent (SNP) | VAF 74/318 reads (23%) | catalogued as rs756158524, COSV60539779; called by muse, mutect2, varscan2
- ZSWIM8 | c.2511G>A p.A837= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs375341128, COSV67131837; called by muse, mutect2, varscan2
- THSD4 | c.1016-70041G>T | Intron (SNP) | VAF 72/216 reads (33%) | called by muse, mutect2, varscan2
